Somatic mutation profile of tumor specimen MP2PRT-PAVMKY-TMP1-A (aliquot MP2PRT-PAVMKY-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVMKY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (586 days).
Specimen MP2PRT-PAVMKY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9adbbe2-1cbd-454e-8c23-7103fc30cadf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMKY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMKY-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b60673e-93bc-4bb8-b160-0d3ffc862f56

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.2756G>A p.R919H | Missense Mutation (SNP) | VAF 24/485 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.915); catalogued as rs765601966; ClinVar: uncertain significance; called by muse, mutect2
- LY6G6C | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 86/464 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs761749993; called by muse, mutect2, varscan2
- UNC5B | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 93/456 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as rs763976725, COSV100100229, COSV58982240; called by muse, mutect2, varscan2
- IGHV1-45 | c.352_353delinsGGAC | In Frame Ins (INS) | VAF 37/146 reads (25%) | called by pindel, varscan2*
- IGHV4-34 | chr14:106373660 GCCTCTCGC>TCCGCAA | Missense Mutation (DEL) | VAF 41/267 reads (15%) | called by pindel, varscan2*
- PID1 | c.121T>A p.S41T | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYBPC3 | c.165C>T p.Y55= | Silent (SNP) | VAF 109/599 reads (18%) | catalogued as rs780012957, COSV99908872; called by muse, mutect2, varscan2
- RBSN | c.15C>T p.D5= | Silent (SNP) | VAF 70/261 reads (27%) | catalogued as rs753112719; called by muse, mutect2, varscan2
- TENM3 | c.303G>A p.A101= | Silent (SNP) | VAF 75/426 reads (18%) | catalogued as rs189642302; called by muse, mutect2, varscan2
